Somatic mutation profile of tumor specimen TCGA-DX-AB2T-01A (aliquot TCGA-DX-AB2T-01A-11D-A387-09) from TCGA case TCGA-DX-AB2T, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 54.1 years (19,749 days).
Specimen TCGA-DX-AB2T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31bc70da-6d53-4aee-83cd-1040e0a14ac4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2T-10A (Blood Derived Normal), aliquot TCGA-DX-AB2T-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d44d3af3-6cba-4cd7-a2f6-54d17f1dd903

The open-access MAF lists 60 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 41, Silent 13, Frame Shift Del 2, Nonsense Mutation 2, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL4 | c.697A>G p.T233A | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV66063600; called by muse, mutect2, varscan2
- ARHGAP35 | c.2612G>T p.R871L | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.325); catalogued as COSV101351236, COSV68331934; called by muse, mutect2, varscan2
- C1R | c.1973C>G p.S658C (on ENST00000536053 / NM_001354346.2; = p.S644C on NM_001733.7) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as COSV101605600, COSV101605625; called by muse, mutect2, varscan2
- C1S | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100196629; called by muse, mutect2, varscan2
- C1S | c.1568G>T p.R523L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV100196630, COSV61071302; called by muse, mutect2
- CD99L2 | c.136T>A p.W46R | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV100692311; called by muse, mutect2, varscan2
- CIITA | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs375497479, COSV60861347; called by muse, mutect2, varscan2
- CSMD3 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52096184, COSV52158214; called by muse, mutect2, varscan2
- CX3CL1 | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs760152855, COSV99136382; called by muse, mutect2, varscan2
- DIP2B | c.2409T>C p.G803= | Splice Region (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99998758; called by muse, mutect2, varscan2
- DOP1A | c.7097A>C p.N2366T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.365); catalogued as COSV99382221; called by muse, mutect2, varscan2
- DSCAM | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101260553; called by muse, mutect2, varscan2
- ELMO2 | c.1510T>A p.Y504N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99281765; called by muse, mutect2, varscan2
- FAM9A | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.087); catalogued as COSV101121355; called by muse, mutect2, varscan2
- FMN2 | c.3461C>T p.P1154L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); catalogued as rs563570840, COSV60419122; called by muse, varscan2
- FOLH1 | c.577A>T p.K193* | Nonsense Mutation (SNP) | VAF 33/180 reads (18%) | catalogued as COSV99923392; called by muse, mutect2, varscan2
- FOLH1 | c.576G>T p.M192I | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV99923396; called by muse, mutect2, varscan2
- FRMPD4 | c.3565C>T p.R1189C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as rs1317974250, COSV66221812, COSV66223127; called by muse, mutect2, varscan2
- GRM4 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs754654198, COSV100946393; called by muse, mutect2, varscan2
- HNRNPD | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV100002964; called by muse, mutect2, varscan2
- IPO5 | c.2296C>T p.L766F | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV99847417; called by muse, mutect2, varscan2
- ITGB4 | c.1373A>T p.E458V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99564204; called by muse, mutect2, varscan2
- KAT2A | c.1651C>A p.L551M | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV99288318; called by muse, mutect2
- KBTBD12 | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.761); catalogued as COSV100675460; called by muse, mutect2, varscan2
- LAMA2 | c.3204G>T p.L1068F | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV101370581; called by muse, mutect2, varscan2
- LRFN2 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV100599659; called by muse, mutect2, varscan2
- LSM14B | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV53378581; called by muse, mutect2
- MAK16 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV100789445; called by muse, mutect2
- MYH7 | c.5452C>T p.R1818W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763073072, CM1411016, COSV62520208; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- NDST3 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.116); catalogued as COSV99630898; called by muse, mutect2, varscan2
- OCLN | c.811A>G p.M271V | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs559132071, COSV100783835; called by muse, mutect2, varscan2
- PCDHB3 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs782736232, COSV50606885, COSV99166133; called by muse, mutect2, varscan2
- PIMREG | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV99338552; called by muse, varscan2
- PIMREG | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.686); catalogued as COSV99338554; called by muse, varscan2
- QSOX2 | c.2003A>T p.Y668F | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100699793; called by muse, mutect2, varscan2
- RANBP10 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58157724; called by mutect2, varscan2
- RNF113B | c.900C>G p.I300M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV99940366; called by muse, mutect2
- SHMT1 | c.731C>A p.P244Q | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100363602; called by muse, mutect2
- SIGLEC11 | c.1157G>T p.S386I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101389445; called by muse, mutect2, varscan2
- SLC16A11 | c.353G>A p.G118D (on ENST00000308009; = p.G94D on NM_153357.3) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752869402, COSV100338685; called by muse, mutect2, varscan2
- STX16 | c.491C>G p.S164W (on ENST00000371141 / NM_001001433.3; = p.S143W on NM_003763.6) | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100397480; called by muse, mutect2, varscan2
- TRPS1 | c.1771A>G p.N591D (on ENST00000220888 / NM_001330599.2; = p.N604D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.262); catalogued as rs370300182; called by muse, mutect2, varscan2
- UHRF2 | c.108C>G p.F36L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.937); catalogued as COSV52797299, COSV99436841, COSV99436863; called by muse, mutect2
- BTBD10 | c.1029_1030del p.Y343* | Nonsense Mutation (DEL) | VAF 87/192 reads (45%) | called by pindel, varscan2
- DDX52 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- RB1 | c.1666_1672del p.R556Wfs*53 | Frame Shift Del (DEL) | VAF 36/49 reads (73%) | called by mutect2, pindel, varscan2
- XRN1 | c.3992del p.N1331Mfs*33 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- AGO2 | c.2220C>T p.I740= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99595915; called by muse, varscan2
- AGO2 | c.2115C>T p.I705= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs2977471, COSV99595916; called by muse, mutect2, varscan2
- AP3D1 | c.3006C>A p.A1002= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100642766; called by muse, mutect2, varscan2
- ARAP3 | c.555C>A p.P185= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs756600715, COSV99499851; called by muse, mutect2, varscan2
- F13A1 | c.861C>T p.G287= | Silent (SNP) | VAF 61/131 reads (47%) | catalogued as rs761512684, COSV53557954, COSV99342130; called by muse, mutect2, varscan2
- FADS3 | c.1060C>A p.R354= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV99605340; called by muse, mutect2
- GPS2 | c.906C>G p.G302= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100223060; called by muse, mutect2, varscan2
- IPO5 | c.2295C>G p.V765= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV99847410; called by muse, mutect2, varscan2
- LRRIQ1 | c.5094A>G p.R1698= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs1280248827, COSV101280594; called by muse, varscan2
- STAG1 | c.1065G>A p.Q355= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV52609424, COSV99365938; called by muse, mutect2, varscan2
- TNFRSF10B | c.261C>A p.I87= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99375436; called by muse, varscan2
- TUBB4A | c.225T>C p.S75= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV99900033; called by muse, mutect2, varscan2
- USH1C | c.1044G>A p.K348= | Silent (SNP) | VAF 37/58 reads (64%) | catalogued as COSV99140362; called by muse, mutect2, varscan2
